Gene-level copy-number profile of tumor specimen TCGA-BR-8295-01A from TCGA case TCGA-BR-8295, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIB; Tumor grade: G3; Age at diagnosis: 60.9 years (22,256 days).
Specimen TCGA-BR-8295-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-STAD.d98eb7a5-2a82-4d77-a280-a45bf1ddf411.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BR-8295-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 805 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/a306ad78-a31d-4991-916a-fe02bd9fa809

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,907; copy number 2: 7,609; copy number 3: 23,728; copy number 4: 8,057; copy number 5: 8,783; copy number 6: 8,666; copy number 7: 37; copy number 8: 22; copy number 10: 9.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-BR-8295-01A-11D-2338-01): tumor purity 0.65, ploidy 3.43, whole-genome doublings 2.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 68 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:215,005,775–217,871,696, 15 genes, copy number 7 (within-gene range 6–7): KCNK2, VDAC1P10, AL450990.1, KCTD3, USH2A, SNORD116, AL358452.1, USH2A-AS2, USH2A-AS1, MRPS18BP1, ESRRG, GPATCH2, SPATA17, SPATA17-AS1, UBBP2.
- chr7:151,012,209–151,277,896, 22 genes, copy number 8 (within-gene range 4–8): ATG9B, ABCB8, AC010973.1, ASIC3, CDK5, SLC4A2, AC010973.3, AC010973.2, FASTK, TMUB1, AGAP3, GBX1, ASB10, IQCA1L, H2BE1, ABCF2-H2BE1, ABCF2, CHPF2, MIR671, SMARCD3, AC021097.1, AC005486.1.
- chr10:31,805,398–32,111,789, 9 genes, copy number 10: ARHGAP12, HMGB1P7, RPL34P19, RN7SL825P, KIF5B, Y_RNA, RPS4XP11, AL161932.2, AL161932.1.
- chr13:99,025,234–99,386,504, 12 genes, copy number 7: RNU6-83P, DOCK9-DT, RPS6P23, UBAC2-AS1, GAPDHP22, UBAC2, RN7SKP9, H2AZP3, GPR18, GPR183, MIR623, HMGB3P4.
- chr14:69,023,150–69,359,308, 10 genes, copy number 7: RPS29P1, DCAF5, DDX18P1, Y_RNA, AL391262.1, AL359317.2, EXD2, AL359317.1, GALNT16, AL157996.1.

Autosomal genes at a single copy (total copy number 1): 486. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
